Somatic mutation profile of tumor specimen HCM-CSHL-1269-C18-06A (aliquot HCM-CSHL-1269-C18-06A-11D-A882-36) from HCMI case HCM-CSHL-1269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 49.4 years (18,035 days).
Specimen HCM-CSHL-1269-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cb76de7-3357-4da9-bf37-7793a11e9e8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1269-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-1269-C18-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e24813e-af32-4f9e-a019-96a9aa5e4c20

The open-access MAF lists 204 somatic variants for this specimen: 158 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 39, Nonsense Mutation 9, Intron 4, Frame Shift Del 3, Splice Region 3, Frame Shift Ins 2, Splice Site 2, 5'UTR 1, In Frame Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 179/351 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 144/341 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1140-1G>A p.X380_splice | Splice Site (SNP) | VAF 166/193 reads (86%) | catalogued as rs1555686594, COSV100748399, COSV61690722; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 124/152 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AARS1 | c.2324_2325del p.S775Cfs*22 | Frame Shift Del (DEL) | VAF 39/322 reads (12%) | catalogued as rs1567601355; called by pindel, varscan2
- ABCA8 | c.2546del p.N849Tfs*28 | Frame Shift Del (DEL) | VAF 74/337 reads (22%) | catalogued as rs755807867; called by mutect2, pindel, varscan2
- ACHE | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 294/608 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1362672573; called by muse, varscan2
- ADAMTS2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs759185076; called by muse, varscan2
- ADGRV1 | c.4309G>C p.E1437Q | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67980221; called by muse, mutect2
- AMER1 | c.714A>C p.K238N | Missense Mutation (SNP) | VAF 154/695 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV57664929, COSV57666849; called by muse, mutect2, varscan2
- AMY1C | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 54/501 reads (11%) | catalogued as rs752371105, COSV64406893; called by muse, mutect2, varscan2
- ANAPC2 | c.1805C>A p.P602Q | Missense Mutation (SNP) | VAF 140/464 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60571567; called by mutect2, varscan2
- ANGPT1 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52437907; called by muse, mutect2, varscan2
- ANKRD30A | c.3505A>G p.K1169E (on ENST00000611781; = p.K1113E on NM_052997.2) | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV100654599; called by muse, mutect2, varscan2
- ARID2 | c.4717G>T p.A1573S | Missense Mutation (SNP) | VAF 234/440 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57604540; called by muse, mutect2, varscan2
- B4GALNT3 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56752219; called by muse, mutect2, varscan2
- C2orf16 | c.797dup p.N266Kfs*2 | Frame Shift Ins (INS) | VAF 93/319 reads (29%) | catalogued as rs1167937523; called by mutect2, varscan2
- C3orf33 | c.239G>A p.R80H (on ENST00000340171 / NM_001308229.2; = p.R37H on NM_173657.2) | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs752205296; called by muse, mutect2, varscan2
- CDR1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 167/768 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as rs761718627, COSV65163988; called by muse, mutect2, varscan2
- CDSN | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 185/885 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs763625404; called by muse, mutect2, varscan2
- COL11A1 | c.4364C>G p.P1455R | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV100615903; called by muse, mutect2, varscan2
- CORIN | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56686267; called by mutect2, varscan2
- EFL1 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs750177180; called by muse, mutect2
- EPB41L3 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs905547822; called by muse, mutect2
- FAT3 | c.11311C>T p.R3771C | Missense Mutation (SNP) | VAF 208/352 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200507277; called by muse, mutect2, varscan2
- FERD3L | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 257/618 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV51761636; called by muse, mutect2, varscan2
- FLG | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 103/424 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs139321371, COSV100910484; called by muse, mutect2, varscan2
- FSTL4 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs138802581; called by muse, varscan2
- GEMIN5 | c.2240C>G p.P747R | Missense Mutation (SNP) | VAF 94/412 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV53562270; called by muse, mutect2, varscan2
- GIMAP1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 191/777 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1381304423, COSV56188765; called by muse, mutect2, varscan2
- GUCY2F | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 81/371 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV54298014; called by muse, mutect2, varscan2
- HCN2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 115/405 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs368817662; called by muse, mutect2, varscan2
- KCNH5 | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as COSV59776894; called by muse, mutect2, varscan2
- KLHL29 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs564002560; called by muse, mutect2, varscan2
- KRT33B | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 252/797 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs931017212, COSV52440908; called by muse, mutect2, varscan2
- LGI2 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1234005410; called by muse, mutect2
- LY6G6F-LY6G6D | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 448/626 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758526333; called by muse, varscan2
- MAP3K10 | c.2483C>T p.T828M | Missense Mutation (SNP) | VAF 174/395 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1347221571; called by muse, mutect2, varscan2
- MPDZ | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 107/379 reads (28%) | catalogued as rs200955619; called by muse, mutect2, varscan2
- MYLK | c.4325A>T p.E1442V | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60622026; called by muse, mutect2
- NOXRED1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs775895152; called by muse, varscan2
- OOSP2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs752322062, COSV53929152, COSV53930487; called by muse, varscan2
- OR14K1 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99315556; called by muse, mutect2
- OR1L6 | c.589G>A p.V197M (on ENST00000373684; = p.V161M on NM_001004453.2) | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769160847; called by muse, mutect2
- OR2AJ1 | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 98/330 reads (30%) | catalogued as rs1478455441; called by muse, mutect2, varscan2
- OR4D5 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 137/485 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs142766960, COSV58305795; called by muse, mutect2, varscan2
- OTUD6B | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV104374805; called by muse, mutect2, varscan2
- PCDH17 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 120/684 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932235; called by muse, varscan2
- PCF11 | c.510C>T p.P170= | Splice Region (SNP) | VAF 70/225 reads (31%) | catalogued as rs780581736; called by muse, mutect2, varscan2
- PLA2R1 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1295711146; called by muse, mutect2, varscan2
- PRR14 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 86/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755490167; called by muse, mutect2, varscan2
- PSKH2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); catalogued as COSV52609254; called by muse, mutect2, varscan2
- PTGER3 | c.809G>C p.S270T | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as rs1441030646; called by muse, mutect2, varscan2
- PTPN12 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99950298; called by muse, mutect2
- RBBP8 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 217/239 reads (91%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs541964555; called by muse, mutect2, varscan2
- RFX8 | c.1393G>A p.V465M (on ENST00000646446; = p.V394M on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/435 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs375213952; called by muse, mutect2, varscan2
- RRAGC | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100883833, COSV65932008; called by muse, mutect2, varscan2
- SLC15A2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 104/469 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs778014741, COSV55195836, COSV55196344; called by muse, mutect2, varscan2
- SMAD6 | c.1440C>G p.F480L | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56594556; called by muse, mutect2, varscan2
- SPOCD1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754308003; called by muse, varscan2
- SSX3 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 139/499 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1454526133, COSV53644128; called by muse, mutect2, varscan2
- SYTL4 | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 155/785 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775999680; called by muse, mutect2, varscan2
- TAF1L | c.5340A>C p.E1780D | Missense Mutation (SNP) | VAF 133/452 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs750348291; called by muse, mutect2, varscan2
- TRPV5 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 184/802 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766349018; called by muse, mutect2, varscan2
- USH2A | c.7526G>A p.R2509Q | Missense Mutation (SNP) | VAF 27/493 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as rs781229974, COSV56374303, COSV99048392; called by muse, mutect2
- WDR19 | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771137155, COSV56469396, COSV56470847; called by muse, mutect2, varscan2
- XKR7 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as rs1257233237, COSV101629288; called by muse, mutect2, varscan2
- ZCCHC18 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 128/624 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62459241; called by muse, varscan2
- ZFP14 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54201777; called by muse, mutect2
- ZNF266 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63221494; called by muse, mutect2, varscan2
- ZNF862 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs760393168, COSV99783639; called by muse, mutect2, varscan2
- ABCA13 | c.10450G>A p.V3484I | Missense Mutation (SNP) | VAF 93/427 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ACACA | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGMO | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AL354761.1 | c.249G>A p.K83= | Splice Region (SNP) | VAF 36/200 reads (18%) | called by muse, varscan2
- ANKRD18A | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- AOC1 | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AP4E1 | c.1741T>C p.S581P | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARG1 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 30/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP22 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 176/437 reads (40%) | called by muse, mutect2, varscan2
- ARMCX6 | c.83C>G p.T28S | Missense Mutation (SNP) | VAF 156/793 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BCKDHB | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 144/728 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BGN | c.855C>A p.D285E | Missense Mutation (SNP) | VAF 134/596 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BICD2 | c.1303T>A p.L435M | Missense Mutation (SNP) | VAF 101/486 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMTA1 | c.2444C>T p.T815I | Missense Mutation (SNP) | VAF 146/351 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CASK | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMKLR1 | c.91T>G p.L31V (on ENST00000312143 / NM_001142344.2; = p.L29V on NM_004072.3) | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- CNR1 | c.52_53del p.T18* | Frame Shift Del (DEL) | VAF 89/451 reads (20%) | called by mutect2, pindel, varscan2
- COL6A6 | c.4742A>C p.K1581T | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- CUX2 | c.3085T>G p.S1029A | Missense Mutation (SNP) | VAF 40/542 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- DCDC1 | c.4803G>T p.K1601N (on ENST00000597505 / NM_001367979.1; = p.K708N on NM_020869.3) | Missense Mutation (SNP) | VAF 27/491 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); called by muse, mutect2
- DGKQ | c.131_132insGCCGGGGCCGGGACCGGG p.G40_P45dup | In Frame Ins (INS) | VAF 15/188 reads (8%) | called by mutect2, varscan2*
- DPY19L1 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPHA4 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 148/489 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ERICH1 | c.368T>G p.F123C | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- FLNB | c.1587G>A p.W529* | Nonsense Mutation (SNP) | VAF 92/203 reads (45%) | called by muse, mutect2, varscan2
- FST | c.471A>C p.E157D | Missense Mutation (SNP) | VAF 22/411 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- GALNT12 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA2 | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HASPIN | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); called by muse, varscan2
- IGSF8 | c.794C>A p.A265E | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- IQSEC3 | c.2272T>C p.F758L (on ENST00000538872 / NM_001170738.2; = p.F455L on NM_015232.1) | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM5B | c.4394C>G p.T1465S | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- KIAA2013 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 163/424 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LILRA1 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRP1B | c.3031T>C p.F1011L | Missense Mutation (SNP) | VAF 132/419 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MMP12 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MRPS9 | c.930-1G>C p.X310_splice | Splice Site (SNP) | VAF 60/240 reads (25%) | called by muse, mutect2, varscan2
- NALCN | c.1174A>C p.S392R | Missense Mutation (SNP) | VAF 136/638 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- NECTIN3 | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 40/622 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2
- NHLH2 | c.334A>T p.K112* | Nonsense Mutation (SNP) | VAF 38/339 reads (11%) | called by muse, mutect2, varscan2
- OR10H3 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 49/552 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2
- OR1L6 | c.327C>A p.C109* (on ENST00000373684; = p.C73* on NM_001004453.2) | Nonsense Mutation (SNP) | VAF 105/350 reads (30%) | called by muse, mutect2, varscan2
- OR2W1 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 46/624 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- PCLO | c.15163G>A p.V5055M | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE4A | c.1019A>C p.K340T (on ENST00000380702 / NM_001111307.2; = p.K101T on NM_006202.3) | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PHF12 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 353/647 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- POT1 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPIG | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 83/317 reads (26%) | called by muse, mutect2, varscan2
- PTBP2 | c.281C>G p.T94S (on ENST00000426398 / NM_001300986.2; = p.T86S on NM_021190.4) | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, mutect2
- PTPN3 | c.1981G>C p.A661P | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB11FIP1 | c.1604C>A p.T535N | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP3 | c.1349C>G p.A450G (on ENST00000402538 / NM_001349975.2; = p.A449G on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2
- RIMS1 | c.4559T>C p.L1520P | Missense Mutation (SNP) | VAF 100/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SAMD9 | c.1178A>C p.K393T | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC16A14 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 113/417 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLC2A13 | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SLC2A14 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SP8 | c.173G>T p.G58V (on ENST00000361443 / NM_198956.4; = p.G76V on NM_182700.6) | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYCP2 | c.2548dup p.S850Kfs*11 | Frame Shift Ins (INS) | VAF 54/323 reads (17%) | called by mutect2, varscan2
- SYNE1 | c.8664T>A p.D2888E (on ENST00000367255 / NM_182961.4; = p.D2895E on NM_033071.3) | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TDRD15 | c.2310C>G p.D770E | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TEX14 | c.3087C>T p.T1029= (on ENST00000240361 / NM_001201457.2; = p.T1023= on NM_031272.5) | Splice Region (SNP) | VAF 58/181 reads (32%) | called by muse, mutect2, varscan2
- THOC5 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR4 | c.1655G>A p.S552N (on ENST00000355622 / NM_138554.5; = p.S512N on NM_003266.4) | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TMEM119 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TNFRSF19 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 74/415 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF8 | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TNRC6B | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TRIP12 | c.2495A>C p.K832T | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TTN | c.102328A>C p.S34110R (on ENST00000591111; = p.S26686R on NM_003319.4) | Missense Mutation (SNP) | VAF 94/296 reads (32%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TXNL4B | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- UBA6 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP2 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- USP53 | c.2245T>G p.L749V | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VCAN | c.2143A>G p.K715E | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- VCAN | c.2144A>T p.K715I | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- VEPH1 | c.2466A>C p.K822N | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- XKR3 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- XRN1 | c.3647C>A p.P1216H | Missense Mutation (SNP) | VAF 77/349 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- XYLT2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- YME1L1 | c.1950A>T p.Q650H (on ENST00000326799 / NM_139312.3; = p.Q593H on NM_014263.4) | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZIM3 | c.550A>C p.S184R | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.925); called by muse, mutect2
- ZNF182 | c.891A>C p.K297N | Missense Mutation (SNP) | VAF 92/605 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF3 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 137/626 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- ZNF462 | c.6761T>G p.L2254R | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF567 | c.931T>A p.C311S (on ENST00000536254 / NM_001322913.1; = p.C280S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF658 | c.854T>G p.V285G | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AHSP | c.150C>T p.N50= | Silent (SNP) | VAF 148/382 reads (39%) | called by muse, mutect2, varscan2
- AMACR | c.864C>T p.D288= | Silent (SNP) | VAF 138/491 reads (28%) | catalogued as rs752187529, COSV56873444; called by muse, mutect2, varscan2
- CASZ1 | c.4950C>G p.G1650= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- CD46 | c.12C>G p.P4= | Silent (SNP) | VAF 99/379 reads (26%) | called by muse, mutect2, varscan2
- CFAP65 | c.1917C>T p.D639= | Silent (SNP) | VAF 134/515 reads (26%) | catalogued as rs145735301; called by muse, mutect2, varscan2
- CHML | c.1143C>T p.G381= | Silent (SNP) | VAF 103/357 reads (29%) | called by muse, mutect2, varscan2
- CORO7 | c.2403G>T p.L801= | Silent (SNP) | VAF 140/644 reads (22%) | called by muse, mutect2, varscan2
- EFL1 | c.663T>A p.S221= | Silent (SNP) | VAF 32/311 reads (10%) | called by muse, mutect2, varscan2
- ELL | c.423G>C p.T141= | Silent (SNP) | VAF 133/521 reads (26%) | called by muse, mutect2, varscan2
- FAM160A1 | c.3117C>T p.C1039= | Silent (SNP) | VAF 66/160 reads (41%) | called by muse, mutect2, varscan2
- FNDC7 | c.1707T>G p.A569= | Silent (SNP) | VAF 118/314 reads (38%) | called by muse, mutect2, varscan2
- HNRNPH2 | c.306G>A p.P102= | Silent (SNP) | VAF 217/955 reads (23%) | catalogued as rs56052724, COSV99516185; called by muse, mutect2, varscan2
- HYDIN | c.11322G>A p.T3774= | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as rs529795965; called by muse, mutect2, varscan2
- MCF2 | c.345T>C p.F115= | Silent (SNP) | VAF 137/602 reads (23%) | called by muse, mutect2, varscan2
- MGAM | c.1131G>A p.A377= | Silent (SNP) | VAF 162/376 reads (43%) | catalogued as rs1554461448, COSV101527453; called by muse, mutect2, varscan2
- MIDEAS | c.1062C>T p.I354= | Silent (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- MYOC | c.1020G>A p.E340= | Silent (SNP) | VAF 142/458 reads (31%) | catalogued as rs534806873; called by muse, mutect2, varscan2
- NACAD | c.1542C>T p.T514= | Silent (SNP) | VAF 95/503 reads (19%) | catalogued as rs1006024629; called by muse, varscan2
- NEDD4 | c.1903A>C p.R635= (on ENST00000508342 / NM_001284338.1; = p.R216= on NM_006154.4) | Silent (SNP) | VAF 14/270 reads (5%) | catalogued as rs923136212; called by muse, mutect2
- NEK9 | c.750G>A p.T250= | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs1040448591, COSV99464532; called by muse, mutect2, varscan2
- OBSCN | c.23652C>T p.V7884= | Silent (SNP) | VAF 32/692 reads (5%) | called by muse, mutect2
- PCDHGA5 | c.1458A>C p.R486= | Silent (SNP) | VAF 116/427 reads (27%) | called by muse, mutect2, varscan2
- PLEC | c.11958G>A p.P3986= (on ENST00000322810 / NM_201380.4; = p.P3876= on NM_000445.5) | Silent (SNP) | VAF 77/188 reads (41%) | catalogued as rs546817334; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLTP | c.726T>G p.T242= | Silent (SNP) | VAF 29/668 reads (4%) | called by muse, mutect2
- POLR3F | c.663C>T p.C221= | Silent (SNP) | VAF 153/484 reads (32%) | catalogued as rs759357302, COSV101112295; called by muse, mutect2, varscan2
- PRAG1 | c.4167G>A p.A1389= | Silent (SNP) | VAF 190/244 reads (78%) | called by muse, mutect2, varscan2
- PTCHD1 | c.234C>T p.R78= | Silent (SNP) | VAF 225/916 reads (25%) | called by muse, mutect2, varscan2
- PTPN4 | c.1734T>G p.T578= | Silent (SNP) | VAF 16/322 reads (5%) | called by muse, mutect2
- RERGL | c.342G>A p.V114= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as COSV57464073; called by muse, mutect2
- SLC16A12 | c.867C>G p.S289= | Silent (SNP) | VAF 129/330 reads (39%) | catalogued as COSV57950652; called by muse, mutect2, varscan2
- SRC | c.183C>T p.P61= | Silent (SNP) | VAF 310/874 reads (35%) | called by muse, varscan2
- TAGLN2 | c.186A>G p.L62= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as rs1377762534, COSV100230954; called by muse, mutect2, varscan2
- TRPS1 | c.3336G>T p.R1112= (on ENST00000220888 / NM_001330599.2; = p.R1125= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/294 reads (41%) | called by muse, mutect2, varscan2
- UBE2A | c.12G>A p.P4= | Silent (SNP) | VAF 270/624 reads (43%) | called by muse, varscan2
- UBE3A | c.1861C>T p.L621= | Silent (SNP) | VAF 75/213 reads (35%) | called by muse, mutect2, varscan2
- UBXN7 | c.744T>G p.S248= | Silent (SNP) | VAF 18/561 reads (3%) | called by muse, mutect2
- USF1 | c.753C>T p.I251= | Silent (SNP) | VAF 34/480 reads (7%) | catalogued as COSV57036135; called by muse, mutect2
- ZIC3 | c.633G>A p.A211= | Silent (SNP) | VAF 172/862 reads (20%) | called by muse, mutect2, varscan2
- ZNF439 | c.1209T>G p.T403= | Silent (SNP) | VAF 114/409 reads (28%) | called by muse, mutect2, varscan2
- CCDC39 | c.2266-565C>A | Intron (SNP) | VAF 68/366 reads (19%) | called by mutect2, varscan2
- DNAH14 | c.2938+1969T>C | Intron (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- MIAT | n.1001C>T | RNA (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- PEG10 | c.*1037C>T | 3'UTR (SNP) | VAF 98/469 reads (21%) | called by muse, mutect2, varscan2
- SUCO | c.-90C>T | 5'UTR (SNP) | VAF 160/604 reads (26%) | catalogued as rs1280934071; called by muse, varscan2
- TTN | c.10360+3975C>T | Intron (SNP) | VAF 62/212 reads (29%) | called by muse, varscan2
- TXNDC8 | c.255+2305A>C | Intron (SNP) | VAF 57/152 reads (38%) | called by muse, mutect2, varscan2
